Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4TA, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4TA-01A (Primary Tumor).

Surgical Pathology

Requested By:

TISSUE DESCRIPTION:

A1 J1 K1 L1 M1 M2 M3 M4 M5 M6 N1 N2 N3 N4 O1 P1 Q1 B1 C1
D1 E1 F1 G1 H1 I1
Right upper lobe lung (205 grams, 2.0 x 2.0 x 0.9 cm), station 2R
(two sets), 4R (six sets), 4L, 7 (three sets), 9, 10R, 11 (two sets)

DIAGNOSIS:

Lung, right upper lobe, lobectomy: Grade 3 (of 4) adenocarcinoma, forming a 2.0 x 2.0 x 0.9 cm subpleural mass that puckers, but does not involve the overlying visceral pleura. The tumor is located 4.2 cm from the bronchial margin. The margins of resection are negative for neoplasm.

Lymph nodes, mediastinal, excision:

- No tumor is identified in multiple (6) right upper paratracheal (station 2R) lymph nodes.
- No tumor is identified in multiple (24) right lower paratracheal (station 4R) lymph nodes.
- No tumor is identified in multiple (5) left lower paratracheal (station 4L) lymph nodes.
- No tumor is identified in multiple (14) subcarinal (station 7) lymph nodes.
- No tumor is identified in a single (1) pulmonary ligament (station 9) lymph node.

Lymph nodes, intrapulmonary/hilar, excision:

- No tumor is identified in multiple (8) intrapulmonary peribronchial lymph nodes.
- No tumor is identified in multiple (2) right hilar (station 10R) lymph nodes.
- No tumor is identified in multiple (2) interlobar (2) lymph nodes.

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: lung, upper lobe C34.1

fw
10/29/12

Source: NCI Genomic Data Commons file eddbd894-411e-47c4-a669-dc0fe3af5fd9 (TCGA-MP-A4TA.B8573F06-EEC4-49A8-943E-7F2EFF3AFBEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).